Somatic mutation profile of tumor specimen TCGA-ZP-A9CZ-01A (aliquot TCGA-ZP-A9CZ-01A-11D-A382-10) from TCGA case TCGA-ZP-A9CZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 72.3 years (26,403 days).
Specimen TCGA-ZP-A9CZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e9ab8b9-95d1-45ad-80ee-50ffa886dec2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZP-A9CZ-10A (Blood Derived Normal), aliquot TCGA-ZP-A9CZ-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/169fc480-f92b-4e64-a034-19e39482d72d

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Nonsense Mutation 2, Splice Site 2, Translation Start Site 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.324A>T p.E108D | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99255886; called by muse, mutect2, varscan2
- ADCY10 | c.2093G>A p.G698D | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs1455092977, COSV100896792; called by muse, mutect2
- AGTRAP | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100065294, COSV58668450; called by muse, varscan2
- APOA4 | c.773C>G p.A258G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV100759308; called by muse, mutect2, varscan2
- ATMIN | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 114/252 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100214597; called by muse, mutect2, varscan2
- BNIPL | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV99764616; called by muse, mutect2, varscan2
- C17orf49 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV101143327; called by muse, mutect2, varscan2
- CACNA1I | c.5857G>A p.A1953T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100359964; called by muse, mutect2, varscan2
- CATSPER3 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99254052; called by muse, mutect2
- CDH9 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1276119336, COSV99143689; called by muse, mutect2, varscan2
- CIITA | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100161796; called by muse, mutect2, varscan2
- EEF2 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100500701; called by muse, mutect2, varscan2
- EHF | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57668406; called by muse, mutect2, varscan2
- FAM216A | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.283); catalogued as rs760081893, COSV100862945; called by muse, mutect2, varscan2
- FUCA2 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99136034; called by muse, mutect2, varscan2
- GRIA1 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV53598636, COSV99601135; called by muse, mutect2, varscan2
- IGHV3-23 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs781828337; called by muse, mutect2, varscan2
- KIF1A | c.2295C>A p.D765E | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.275); catalogued as rs780908328, COSV100240645; called by muse, mutect2, varscan2
- KL | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867215187, COSV66309246; called by muse, mutect2, varscan2
- KRT74 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV99977487; called by muse, mutect2, varscan2
- LDHB | c.233T>G p.I78S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV100636401; called by muse, mutect2, varscan2
- MYO7A | c.4465G>A p.V1489I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs1265094428, COSV68683839; called by muse, mutect2, varscan2
- NF1 | c.4630G>A p.A1544T (on ENST00000358273 / NM_001042492.3; = p.A1523T on NM_000267.3) | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100646732; called by muse, mutect2, varscan2
- NFATC4 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV51613485; called by muse, mutect2, varscan2
- NTRK2 | c.2293T>C p.C765R (on ENST00000323115 / NM_001369534.1; = p.C781R on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52884155; called by muse, mutect2, varscan2
- PLA2G6 | c.1078-1G>C p.X360_splice | Splice Site (SNP) | VAF 31/110 reads (28%) | catalogued as COSV59271082, COSV59272537; called by muse, mutect2, varscan2
- POLR3E | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100242086; called by muse, mutect2
- PPIG | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 127/391 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644443; called by muse, mutect2, varscan2
- PRKG1 | c.1685T>C p.L562P | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100907236; called by muse, mutect2, varscan2
- PSMC5 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV99856361; called by muse, mutect2, varscan2
- PTP4A3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs1207702316, COSV100267188; called by muse, mutect2, varscan2
- RBL2 | c.926dup p.L310Afs*3 | Frame Shift Ins (INS) | VAF 64/127 reads (50%) | catalogued as rs1401758241; called by mutect2, varscan2
- SCRIB | c.4747+1G>A p.X1583_splice | Splice Site (SNP) | VAF 135/211 reads (64%) | catalogued as COSV100253070; called by muse, mutect2, varscan2
- SF3B2 | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV100488394; called by muse, mutect2, varscan2
- SLIT1 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs770689075, COSV56594403; called by muse, mutect2, varscan2
- SNAP91 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as COSV99535021; called by muse, mutect2, varscan2
- SUGCT | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1351260368, COSV100001224, COSV59324050; called by muse, mutect2, varscan2
- SUZ12 | c.1471A>G p.I491V | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs1195143657, COSV100496844; called by muse, mutect2, varscan2
- SYNGAP1 | c.3532T>C p.Y1178H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.892); catalogued as COSV99538236; called by muse, mutect2, varscan2
- TRPC3 | c.1357C>T p.R453* (on ENST00000379645 / NM_001366479.2; = p.R380* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as rs1382442696, COSV53382243; called by muse, mutect2, varscan2
- ZNF804B | c.3884T>A p.L1295* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV100303305; called by muse, mutect2, varscan2
- LENG9 | c.371del p.R124Pfs*114 | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- SMPD1 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- EPN2 | c.450C>G p.T150= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100127553; called by muse, mutect2, varscan2
- GPHN | c.1020T>A p.L340= (on ENST00000315266 / NM_001377519.1; = p.L373= on NM_020806.5) | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs766338596, COSV100016002; called by muse, mutect2, varscan2
- MXRA5 | c.6261C>G p.T2087= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV99476632; called by muse, mutect2, varscan2
- MYT1 | c.1434C>T p.A478= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100114471; called by muse, mutect2, varscan2
- PATJ | c.1986C>T p.D662= | Silent (SNP) | VAF 35/183 reads (19%) | catalogued as COSV100333959; called by muse, mutect2, varscan2
- PCDHA4 | c.1734C>T p.S578= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100793351; called by muse, mutect2, varscan2
- SLC6A20 | c.600G>A p.A200= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs780083357, COSV62071108; called by muse, mutect2, varscan2
- SMAD7 | c.90A>G p.G30= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100052851; called by muse, mutect2
- TMEM39B | c.1215C>T p.D405= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs373923538; called by muse, mutect2, varscan2
- TSGA13 | c.636T>C p.H212= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV100449622; called by muse, mutect2, varscan2
- ZNF648 | c.540A>G p.V180= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100374542; called by muse, mutect2, varscan2
- BACE2 | c.312+10724G>C | Intron (SNP) | VAF 39/132 reads (30%) | called by muse, mutect2, varscan2
- NXF5 | n.1347T>A | RNA (SNP) | VAF 169/239 reads (71%) | catalogued as COSV99534316; called by muse, mutect2, varscan2
